CCDI case PBCVWA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/075d53e1-5ccc-4762-96f2-cd9c766c632b

Demographics
Sex at birth: female.

Biospecimens (4 samples)
- Sample 0E0YBH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0E0YCY, 0E1MC1 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E0YD5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
